Surgical pathology report (de-identified scan), TCGA case TCGA-CX-7085, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Medical College of Georgia, specimen TCGA-CX-7085-01A (Primary Tumor).

[page 1 of 7]
TCGA 8003

F i n a l P a t h o l o g y D i a g n o s i s R e p o r t

Accession Number: Senior Pathologist:

Collected Date/Time:

Received Date/Time:

Verified Date/Time:

Final Pathologic Diagnosis

A) RIGHT TONGUE (PARTIAL GLOSSECTOMY):

- Invasive squamous cell carcinoma, keratinizing (see synoptic report).

B) ANTERIOR DEEP MARGIN (BIOPSY):

- Negative for malignancy.

C) ANTERIOR LATERAL MARGIN (BIOPSY):

- Negative for malignancy.

D) POSTERIOR MEDIAL MARGIN (BIOPSY):

- Negative for malignancy.

E) POSTERIOR LATERAL MARGIN (BIOPSY):

- Negative for malignancy.

F) POSTERIOR DEEP MARGIN (BIOPSY):

- Negative for malignancy.

G) POSTERIOR MARGIN (BIOPSY):

- Negative for malignancy.

H) ANTERIOR MEDIAL MARGIN (BIOPSY):

- Negative for malignancy.

I) RIGHT LEVEL 1 (EXCISION):

- Two lymph nodes, negative for malignancy (0/2).
- Salivary gland with chronic sialadenitis.

[page 2 of 7]
F i n a l P a t h o l o g y D i a g n o s i s R e p o r t

Accession Number: Senior Pathologist:

Collected Date/Time:

Received Date/Time:

Verified Date/Time:

J) RIGHT LEVEL 2 (EXCISION):

- Eight lymph nodes, negative for malignancy (0/8).

K) RIGHT LEVEL 3 (EXCISION):

- Six lymph nodes, negative for malignancy (0/6).

L) RIGHT LEVEL 4 (EXCISION):

- Nine lymph nodes, negative for malignancy (0/9).

I attest I have personally reviewed the specimen/slides and agree with the above findings.

Resident:

Synoptic Report.

A: Lip and Oral Cavity - MCGH

SPECIMEN (Select all that apply):

Other (specify): Right Anterior Tongue

RECEIVED:

Fresh

PROCEDURE (Select all that apply):

Resection

Other (specify): Partial Glossectomy

SPECIMEN INTEGRITY:

Intact

SPECIMEN SIZE:

Greatest dimensions: 4.2 x 2.5 x 1.3 cm

SPECIMEN LATERALITY:

Right

TUMOR SITE (Select all that apply):

Anterior two-thirds of tongue, NOS

[page 3 of 7]
F i n a l P a t h o l o g y D i a g n o s i s R e p o r t

Accession Number: Senior Pathologist:

Collected Date/Time:

Received Date/Time:

Verified Date/Time:

TUMOR FOCALITY:

Single focus

TUMOR SIZE:

Greatest dimensions: 1.6 cm

TUMOR THICKNESS (pT1 AND pT2 Tumors):

Tumor thickness: 9 mm

TUMOR DESCRIPTION (Select all that apply):

Gross subtype

Endophytic

MACROSCOPIC EXTENT OF TUMOR:

Specify: Limited to resection specimen margins

HISTOLOGIC TYPE (Select all that apply):

Squamous cell carcinoma, conventional

HISTOLOGIC GRADE:

G2: Moderately differentiated

MARGINS (Select all that apply):

Margins uninvolved by invasive carcinoma

Distance from closest margin: 1 mm

Specify margin(s), per orientation, if possible: Deep Margin

Margins uninvolved by carcinoma in situ (includes moderate and severe dysplasia)

Distance from closest margin: 12 mm

TREATMENT EFFECT:

Not identified

LYMPH-VASCULAR INVASION:

Not identified

PERINEURAL INVASION:

Present

LYMPH NODES, EXTRANODAL EXTENSION:

Not identified

PATHOLOGIC STAGING (pTNM):

PRIMARY TUMOR (pT)

pT1: Tumor 2 cm or less in greatest dimension

REGIONAL LYMPH NODES (pN)

pN0: No regional lymph node metastasis

Specify: Number examined: 25

Number involved: 0

DISTANT METASTASIS

Not Applicable

ADDITIONAL PATHOLOGIC FINDINGS (Select all that apply):

[page 4 of 7]
F i n a l P a t h o l o g y D i a g n o s i s R e p o r t

Accession Number: Senior Pathologist:

Collected Date/Time:

Received Date/Time:

Verified Date/Time:

Keratinizing Dysplasia

Moderate

Inflammation (specify type): Chronic

Intraoperative Diagnosis

FS B1: Negative for neoplasia.

FS C1: Negative for neoplasia.

FS D1: Negative for neoplasia.

FS E1: Negative for neoplasia.

FS F1: Negative for neoplasia.

FS G1: Negative for neoplasia.

FS H1: Negative for neoplasia.

Clinical History

Tumor Bank.

Pre/Post-operative Diagnosis

SCCA of tongue.

Gross Anatomic Description

(Dictated by

Specimens received in eight containers.

Specimen A: Designated "right tongue lesion, non-marginal tissue" is received fresh for Tumor Bank labeled with the patient's name and "right tongue lesion, non-marginal tissue". Specimen consists of a single portion of soft tan/pink tongue measuring 4.2 x 2.5 x 1.3 cm. The surface is focally smooth with areas of erythema and irregularity. The surgical margin is inked blue. The specimen is unoriented. Cut surface is tan/yellow and focally hemorrhagic and possibly necrotic with a central white tumor measuring up to 1.6 cm in greatest dimension.

Section code: A1 – tips; A2-A10 – remainder of specimen serially sectioned.

Specimen B: Designated "anterior deep" is received fresh for intraoperative consultation and frozen section diagnosis on labeled with the patient's name and "anterior deep". Specimen consists of one piece of red/tan tissue 0.9 x 0.6 x 0.2 cm, entirely frozen.

[page 5 of 7]
F i n a l P a t h o l o g y D i a g n o s i s R e p o r t

Accession Number: Senior Pathologist:

Collected Date/Time:

Received Date/Time:

Verified Date/Time:

Section code: B1 – frozen section control, entire specimen.

Specimen C: Designated "anterior lateral" is received fresh for intraoperative consultation and frozen section diagnosis on [REDACTED] labeled with the patient's name and "anterior lateral". Specimen consists of one piece of tan tissue 2.5 x 0.2 x 0.1 cm, bisected.

Section code: C1 – frozen section control.

Specimen D: Designated "posterior medial" is received fresh for intraoperative consultation and frozen section diagnosis on [REDACTED] labeled with the patient's name and "posterior medial". Specimen consists of one piece of tan tissue 2.4 x 0.2 x 0.1 cm, bisected.

Section code: D1 – frozen section control, entire specimen.

Specimen E: Designated "posterior lateral" is received fresh for intraoperative consultation and frozen section diagnosis on [REDACTED] labeled with the patient's name and "posterior lateral". Specimen consists of one piece of red tissue 2.0 x 0.2 x 0.12 cm, bisected.

Section code: E1 – frozen section control, entire specimen.

Specimen F: Designated "posterior deep" is received fresh for intraoperative consultation and frozen section diagnosis on [REDACTED] labeled with the patient's name and "posterior deep". Specimen consists of two pieces of red tissue 0.9 x 0.7 x 0.2 cm and 0.3 x 0.1 x 0.1 cm, entirely frozen.

Section code: F1 – frozen section control.

Specimen G: Designated "posterior margin" is received fresh for intraoperative consultation and frozen section diagnosis on [REDACTED] labeled with the patient's name and "posterior margin". Specimen consists of one piece of red tissue 0.8 x 0.2 x 0.1 cm, entirely frozen.

Section code: G1 – frozen section control, entire specimen.

Specimen H: Designated "anterior medial" is received fresh for intraoperative consultation and frozen section diagnosis on [REDACTED] labeled with the patient's name and "anterior medial". Specimen consists of one piece of tan tissue 3.0 x 0.2 x 0.2 cm, entirely frozen. Specimen is trisected.

Section code: H1 – frozen section control, entire specimen.

Specimen I: Designated "right level one" is received fresh for Tumor Bank labeled with the patient's name and "right level one". Specimen consists of a single packet of light tan/yellow fibroadipose tissue measuring 5.0 x 4.0 x 2.0 cm in greatest dimension. No grossly evident tumor is present. No specimen is sent for Tumor Bank. The specimen consists of a well encapsulated unremarkable submandibular gland measuring 4.5 x 3.0 x 1.7 cm in greatest dimension and associated fibroadipose tissue measuring 3.5 x 2.0 x 1.4 cm in greatest dimension. The submandibular gland is serially sectioned to reveal no evidence of tumor. No associated lymphoid tissue is identified immediately surrounding the submandibular gland. The cut surface of the submandibular gland is light tan/yellow and homogenous in nature.

Printed: [REDACTED]

[page 6 of 7]
F i n a l P a t h o l o g y D i a g n o s i s R e p o r t

Accession Number: Senior Pathologist:

Collected Date/Time:

Received Date/Time:

Verified Date/Time:

Section code: I1 – five possible lymph nodes submitted intact; I2-I3 – remainder of associated fibroadipose tissue; I4-I5 – representative sections of submandibular gland.

Specimen J: Designated "right level 2" is received fresh for Tumor Bank labeled with the patient's name and "right level 2". Specimen consists of a single packet of light tan/yellow fibroadipose tissue measuring 4.0 x 2.5 x 1.2 cm in greatest dimension. No grossly evident tumor is identified. No specimen is sent for Tumor Bank.

Section code: J1 – four possible lymph nodes submitted intact; J2- one lymph node, bisected; J3-J4 – remainder of associated fibroadipose tissue.

Specimen K: Designated "right level three" is received fresh for Tumor Bank labeled with the patient's name and "right level three". Specimen consists of a single packet of light tan/yellow fibroadipose tissue measuring 3.5 x 2.3 x 1.1 cm in greatest dimension. No grossly evident tumor is identified. No specimen is sent for Tumor Bank.

Section code: K1 – four possible lymph nodes submitted intact; K2- two possible lymph nodes, submitted intact; K3-K4 – remainder of fibroadipose tissue.

Specimen L: Designated "right level four" is received fresh for Tumor Bank labeled with the patient's name and "right level four". Specimen consists of a single packet of light tan/yellow fibroadipose tissue measuring 3.8 x 2.8 x 1.4 cm in greatest dimension. No grossly visible tumor is present throughout the lymph node packet. No specimen is given for Tumor Bank.

Section code: L1 – six possible lymph nodes submitted intact; L2- one lymph node, bisected; L3- one lymph node bisected; L4-L6 – remainder of fibroadipose tissue, submitted entirely.

[page 7 of 7]
I n t r a o p e r a t i v e D i a g n o s i s R e p o r t

Accession Number: Senior Pathologist:

Collected Date/Time:

Received Date/Time:

Verified Date/Time:

Intraoperative Diagnosis

FS B1: Negative for neoplasia.

FS C1: Negative for neoplasia.

FS D1: Negative for neoplasia.

FS E1: Negative for neoplasia.

FS F1: Negative for neoplasia.

FS G1: Negative for neoplasia.

FS H1: Negative for neoplasia.

Source: NCI Genomic Data Commons file 3c8cfd20-22c2-4cbb-b39e-ff031f706971 (TCGA-CX-7085.43FA648F-C530-40CE-91DD-5848BD3676A1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).